Gene-level copy-number profile of tumor specimen TCGA-2Y-A9GS-01A from TCGA case TCGA-2Y-A9GS, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 58.4 years (21,318 days).
Specimen TCGA-2Y-A9GS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.cdcb5fda-e3b4-4524-87b6-b173e2203fe3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9GS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af2fd757-a5b6-4542-bc99-c939e5bfd5a2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,941; copy number 2: 43,452; copy number 3: 2,313; copy number 4: 70; copy number 25: 36; copy number 27: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9GS-01A-12D-A381-01): tumor purity 0.71, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 44 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,870,664–70,015,815, 33 genes, copy number 25: LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2.
- chr11:70,862,790–70,896,305, 3 genes, copy number 25: SHANK2-AS3, MIR3664, AP003783.1.
- chr11:71,814,045–71,928,654, 8 genes, copy number 27 (within-gene range 2–27): ZNF705E, DEFB108B, RNA5SP342, DEFB130C, AP002495.1, DEFB131B, OR7E128P, OR7E126P.

Autosomal genes at a single copy (total copy number 1): 11,555. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
